Gene-level copy-number profile of tumor specimen ALCH-AE1B-TTP1-A from ALCHEMIST case ALCH-AE1B, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 75.5 years (27,562 days).
Specimen ALCH-AE1B-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 12ec28ae-14f0-4c49-939b-9a6ef7de3809.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AE1B-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,227 have no estimate.
https://portal.gdc.cancer.gov/files/27d1eb67-d456-4948-8811-a45257cc96fb

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 20; copy number 1: 553; copy number 2: 55,433; copy number 3: 2,376; copy number 4: 11; copy number 23: 3.

Homozygous deletions (total copy number 0; autosomes only): 20 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:87,629,755–87,655,243, 2 genes: MIR4435-1, RPS14P5.
- chr3:57,134,142–57,134,723, 1 gene (within-gene range 0–2): AC097358.1.
- chr7:27,106,184–27,158,976, 10 genes: HOXA3, HOXA-AS2, HOXA4, AC004080.6, HOXA-AS3, HOXA5, HOXA6, AC004080.5, HOXA7, AC004080.4.
- chr10:79,000,484–79,003,803, 1 gene (within-gene range 0–2): AL356753.1.
- chr11:31,784,779–31,817,961, 1 gene (within-gene range 0–2): PAX6.
- chr13:113,324,163–113,364,148, 3 genes (within-gene range 0–2): GRTP1, AL136221.1, GRTP1-AS1.
- chr16:3,100,696–3,143,734, 1 gene (within-gene range 0–2): ZNF213-AS1.
- chr16:3,112,560–3,120,517, 1 gene (within-gene range 0–2): ZNF205.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr22:18,906,028–18,947,732, 3 genes, copy number 23 (within-gene range 1–23): DGCR6, AC007326.4, PRODH.

Autosomal genes at a single copy (total copy number 1): 553. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
